Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2I, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2I-01A (Primary Tumor).

Male
Surgery Date:

DIAGNOSIS:

Liver, segments V and VI, resection: Grade 2 (of 4) intrahepatic cholangiocarcinoma forming a 6.8 x 6.6 x 5.8 cm multilobulated mass. Tumor extends to 0.3 cm from the surgical resection margin.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

7/3/8/14

Source: NCI Genomic Data Commons file a6c831a7-ed7c-4309-96b5-c1f2c9dcf679 (TCGA-W5-AA2I.7C977B78-0280-4078-BA64-4D8D9554B38F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).